Somatic mutation profile of tumor specimen CDDP-ABKV-TTP1-A (aliquot CDDP-ABKV-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABKV, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57 years.
Specimen CDDP-ABKV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3d7bacb-ba76-4f58-bbef-efdb7446a0c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABKV-NB1-A (Blood Derived Normal), aliquot CDDP-ABKV-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f1cf4b0-84fc-4285-9f0c-29407cae912e

The open-access MAF lists 299 somatic variants for this specimen: 198 protein-altering or splice-affecting, 61 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 61, Intron 22, Nonsense Mutation 11, Frame Shift Del 9, 5'UTR 6, RNA 4, 3'Flank 3, Splice Site 3, 5'Flank 3, 3'UTR 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.2255C>G p.S752C | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV70037515; called by muse, mutect2, varscan2
- ACOT7 | c.485A>T p.Y162F (on ENST00000377855 / NM_181864.3; = p.Y152F on NM_007274.4) | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV64114626; called by muse, mutect2, varscan2
- ADAM23 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV100008680, COSV52223107; called by muse, mutect2, varscan2
- AFF1 | c.1235A>C p.H412P | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.423); catalogued as COSV57122201; called by muse, mutect2, varscan2
- AK9 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs746980960, COSV58146307; called by muse, mutect2, varscan2
- ARFGEF2 | c.5236G>A p.D1746N | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as COSV100904287, COSV64213862; called by muse, mutect2, varscan2
- ARID2 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV57610215; called by muse, mutect2, varscan2
- ARPP21 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 40/132 reads (30%) | catalogued as COSV51803367; called by muse, mutect2, varscan2
- ASTN2 | c.602A>T p.Q201L | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV57799770; called by muse, mutect2, varscan2
- BOD1L2 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV73996916; called by muse, varscan2
- BRWD3 | c.5108G>T p.G1703V | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.127); catalogued as COSV64751508; called by muse, mutect2, varscan2
- C2CD3 | c.4327G>T p.D1443Y | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58096658; called by muse, mutect2, varscan2
- C4orf50 | c.292G>C p.E98Q (on ENST00000324058; = p.E1330Q on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100135792; called by muse, mutect2, varscan2
- C4orf54 | c.2390C>T p.T797I | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1271773244; called by muse, mutect2, varscan2
- C5orf47 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV60865122; called by muse, varscan2
- CASK | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.758); catalogued as COSV59371885; called by muse, mutect2, varscan2
- CD2AP | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.419); catalogued as COSV63761876; called by muse, mutect2, varscan2
- CENATAC | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV57723331; called by muse, mutect2, varscan2
- CIART | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV51745274; called by muse, mutect2, varscan2
- CNST | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs1340982369; called by muse, mutect2, varscan2
- CSMD3 | c.1271G>T p.S424I | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV52254000; called by muse, mutect2, varscan2
- CSMD3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 60/533 reads (11%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.967); catalogued as rs536561292, COSV52113015; called by muse, mutect2, varscan2
- CYP24A1 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV53775770; called by muse, mutect2, varscan2
- DCP2 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66617746; called by muse, mutect2, varscan2
- DDX23 | c.1662G>A p.M554I | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56399849; called by muse, mutect2, varscan2
- DIDO1 | c.6584G>C p.R2195T | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV56629380; called by muse, mutect2, varscan2
- DISP3 | c.3395C>A p.S1132Y | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53833305; called by muse, mutect2, varscan2
- DNAH5 | c.8492C>G p.A2831G | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV54240701; called by muse, mutect2, varscan2
- DNAH5 | c.3712G>A p.E1238K | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs762166377, COSV54233154, COSV54240709; called by muse, mutect2, varscan2
- DNMT3L | c.509G>C p.R170P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as COSV99533320; called by muse, mutect2, varscan2
- DSTYK | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | catalogued as COSV65687396, COSV65687558; called by muse, varscan2
- ENOX1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV54904614, COSV54909270; called by muse, mutect2, varscan2
- EPB41 | c.2345G>C p.G782A (on ENST00000343067 / NM_001166005.2; = p.G573A on NM_203342.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/444 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV58046703; called by muse, mutect2, varscan2
- EPS8L3 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV62610069; called by muse, varscan2
- ESAM | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs764844339, COSV54036038; called by muse, mutect2, varscan2
- FAM53A | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV57401700; called by muse, mutect2, varscan2
- FAM83H | c.3130C>G p.L1044V | Missense Mutation (SNP) | VAF 94/532 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62029301; called by muse, mutect2, varscan2
- FLG | c.7799G>C p.R2600T | Missense Mutation (SNP) | VAF 69/562 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV100912246, COSV64245155; called by muse, mutect2, varscan2
- FLT1 | c.2628G>T p.M876I | Missense Mutation (SNP) | VAF 94/493 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56718051, COSV56735255; called by muse, mutect2, varscan2
- FREM3 | c.4594G>A p.D1532N | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1310526321, COSV61681743; called by muse, mutect2, varscan2
- GALNT2 | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV64196948; called by muse, mutect2, varscan2
- GBX2 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV60445576; called by muse, mutect2, varscan2
- GPR137 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV57403153; called by muse, mutect2, varscan2
- GRM4 | c.2646C>A p.N882K | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65210371, COSV65216483; called by muse, mutect2, varscan2
- GSDMC | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759624672, COSV52696137; called by muse, mutect2, varscan2
- GUCY2D | c.2352G>A p.M784I | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV54697622; called by muse, mutect2, varscan2
- H2AC17 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.868); catalogued as rs760322400; called by muse, mutect2
- H2BC5 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); catalogued as COSV56802589; called by muse, mutect2, varscan2
- HAGH | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV68400890; called by muse, mutect2, varscan2
- HBP1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56018650; called by muse, mutect2, varscan2
- HECTD4 | c.2465A>T p.N822I | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61180699; called by muse, mutect2, varscan2
- HERC2 | c.9097G>T p.V3033L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV55338309; called by muse, mutect2, varscan2
- HNRNPLL | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55368612; called by muse, mutect2
- IFIT2 | c.661A>C p.K221Q | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV51079988; called by muse, mutect2, varscan2
- IGFLR1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 140/349 reads (40%) | catalogued as COSV53075421; called by muse, mutect2, varscan2
- INO80C | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV52034611; called by muse, mutect2, varscan2
- INSIG2 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 43/176 reads (24%) | catalogued as COSV55523178; called by muse, mutect2, varscan2
- IPO9 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV64234756; called by muse, varscan2
- JAK1 | c.2739G>C p.E913D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61094358; called by muse, mutect2, varscan2
- JTB | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs746057733, COSV55132822; called by muse, mutect2, varscan2
- KCNC1 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56396430; called by muse, mutect2, varscan2
- KDM3B | c.4507G>C p.E1503Q | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV58693202, COSV58694566; called by muse, mutect2, varscan2
- KDR | c.598T>G p.C200G | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55771397; called by muse, mutect2, varscan2
- KEAP1 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50480137, COSV99407912; called by muse, mutect2, varscan2
- KIF2C | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV64764324, COSV64765217; called by muse, mutect2, varscan2
- KIF5A | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV54052562; called by mutect2, varscan2
- KRTAP20-3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); catalogued as COSV66999861; called by muse, mutect2, varscan2
- LCOR | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.31); catalogued as COSV53717314, COSV53717365; called by muse, mutect2, varscan2
- LDLRAD1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV62810089; called by muse, mutect2, varscan2
- LHCGR | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs979633619, COSV54295551, COSV54300568; called by muse, mutect2, varscan2
- LRFN1 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 169/428 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50481156; called by muse, mutect2, varscan2
- LRFN5 | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53267765, COSV99982616; called by muse, mutect2, varscan2
- LRRC66 | c.1901G>T p.S634I | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV58635502; called by muse, mutect2, varscan2
- LRRC74A | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as rs769708746, COSV53611362, COSV99372774; called by muse, mutect2, varscan2
- MAGEC1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs774360885, COSV53577524; called by muse, mutect2, varscan2
- MALRD1 | c.2305A>C p.N769H | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772542193; called by muse, mutect2, varscan2
- MAOA | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.263); catalogued as COSV58644341, COSV58644828; called by muse, mutect2, varscan2
- MUC16 | c.35617G>A p.E11873K | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.076); catalogued as rs750033579, COSV67480538; called by muse, mutect2, varscan2
- MYCBP2 | c.2429G>T p.G810V (on ENST00000357337; = p.G848V on NM_015057.5) | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV62012426; called by muse, mutect2, varscan2
- MYO5A | c.2561G>C p.R854T | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62562700; called by muse, varscan2
- NCOA3 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV59071158; called by muse, mutect2, varscan2
- NDEL1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs142254099; called by muse, mutect2, varscan2
- NFKB2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51873881; called by muse, mutect2, varscan2
- NLGN3 | c.2140G>A p.V714M (on ENST00000358741 / NM_181303.2; = p.V694M on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1018462994, COSV62444523; called by muse, mutect2, varscan2
- NWD2 | c.2188C>A p.L730I | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV58754596; called by muse, mutect2, varscan2
- OR4L1 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV59850686; called by muse, mutect2, varscan2
- OR52E8 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV66205815, COSV66205972, COSV66209543; called by muse, mutect2, varscan2
- OR5B17 | c.539C>A p.P180Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV62160719; called by muse, varscan2
- OR5D14 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV59456549; called by muse, mutect2
- OTUD4 | c.1052C>G p.S351C (on ENST00000447906 / NM_001366057.1; = p.S286C on NM_001102653.1) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); catalogued as COSV71382089; called by muse, mutect2, varscan2
- PAPPA2 | c.1871G>C p.R624T | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV100866858, COSV62782438; called by muse, mutect2, varscan2
- PAXIP1 | c.1328A>T p.Q443L | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV68186975; called by muse, varscan2
- PCDHGA8 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53993274; called by muse, mutect2, varscan2
- PCED1A | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 82/500 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62313286; called by muse, mutect2, varscan2
- PLXNB1 | c.3928A>T p.T1310S | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as COSV56492264; called by muse, mutect2, varscan2
- PLXND1 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV60709978; called by muse, mutect2, varscan2
- PNISR | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65080115; called by muse, mutect2, varscan2
- PRLH | c.99C>T p.R33= | Splice Region (SNP) | VAF 26/112 reads (23%) | catalogued as COSV51255553; called by muse, mutect2, varscan2
- PTGR2 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV50866505; called by muse, mutect2, varscan2
- PXDN | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.447); catalogued as COSV53241228, COSV99414813; called by muse, mutect2, varscan2
- RBBP8 | c.1984G>C p.D662H | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59094700; called by muse, mutect2, varscan2
- RBMS1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV62355369; called by muse, mutect2, varscan2
- REG3A | c.409C>G p.P137A | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); catalogued as rs200652760, COSV59410702, COSV59411864; called by muse, mutect2, varscan2
- RIT2 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56295004; called by muse, mutect2, varscan2
- RLF | c.4633G>A p.E1545K | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV65652567; called by muse, mutect2, varscan2
- RYR2 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63700475; called by muse, mutect2, varscan2
- SCAPER | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57747356; called by muse, mutect2, varscan2
- SCN3A | c.3963G>A p.M1321I | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV51821716; called by muse, varscan2
- SDK2 | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs764192799, COSV66186362; called by muse, mutect2, varscan2
- SEMA5B | c.2768C>G p.S923* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV52103617; called by muse, mutect2, varscan2
- SKIL | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV52061330; called by muse, mutect2, varscan2
- SLK | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1294111959, COSV59827452; called by muse, mutect2, varscan2
- SNTB2 | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1293815553; called by muse, mutect2, varscan2
- SPINK5 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1356598877, COSV56258999; called by muse, mutect2, varscan2
- SPIRE1 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV59159691; called by muse, mutect2, varscan2
- SRRM2 | c.2702C>G p.S901C | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as rs781471600, COSV57077600; called by muse, mutect2, varscan2
- SRRM2 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs376948735; called by muse, mutect2, varscan2
- SRRT | c.2149C>G p.L717V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53819842; called by muse, mutect2, varscan2
- SRSF5 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 78/429 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs142745234; called by muse, mutect2, varscan2
- ST3GAL3 | c.611C>T p.S204L (on ENST00000361392 / NM_174964.4; = p.S189L on NM_006279.5) | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV53517629; called by muse, varscan2
- STIL | c.2703G>T p.Q901H | Missense Mutation (SNP) | VAF 62/317 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV54550660, COSV54552081; called by muse, mutect2, varscan2
- TGM6 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 87/328 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs761552290, COSV52484072; called by muse, mutect2, varscan2
- THSD7A | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); catalogued as COSV70269046; called by muse, mutect2, varscan2
- TRPM1 | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV56638610; called by muse, mutect2, varscan2
- USH2A | c.6467C>A p.S2156Y | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56404541; called by muse, mutect2, varscan2
- XKR7 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs748725549, COSV73812885; called by muse, mutect2, varscan2
- ZC3H10 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV57769597; called by muse, mutect2, varscan2
- ZFYVE19 | c.1069G>T p.D357Y (on ENST00000355341 / NM_001077268.2; = p.D347Y on NM_032850.5) | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV54541489; called by muse, mutect2
- ZNF234 | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 165/380 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70603463, COSV70603731; called by muse, mutect2, varscan2
- ZNF267 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56254733; called by muse, mutect2, varscan2
- ZNF267 | c.1617G>C p.E539D | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV56254746; called by muse, mutect2, varscan2
- ZNF343 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); catalogued as COSV53854912; called by muse, mutect2, varscan2
- ZNF589 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as rs1354380212, COSV61220792; called by muse, mutect2, varscan2
- ZNF589 | c.960C>G p.I320M | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV61220797, COSV61220916; called by muse, mutect2, varscan2
- ZNF696 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV57525403; called by muse, varscan2
- ZNF696 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV57525412; called by muse, varscan2
- ZNF83 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV56531319; called by muse, mutect2, varscan2
- ZNF83 | c.151T>A p.S51T | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV56531328; called by muse, mutect2, varscan2
- AARS1 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 75/430 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADAMTSL2 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.3187G>T p.V1063L (on ENST00000506720 / NM_001322402.2; = p.V995L on NM_015236.6) | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- AP1M2 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARID4B | c.1969C>G p.P657A | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- C1orf167 | c.4205C>T p.S1402L | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- CAMKMT | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CD226 | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, varscan2
- CENPF | c.8896C>T p.H2966Y | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHCHD10 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, varscan2
- CROCC2 | c.3520G>C p.E1174Q | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- CTNNA1 | c.2315del p.C772Sfs*19 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | called by mutect2, pindel, varscan2
- DNAJA2 | c.402del p.K134Nfs*37 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- DST | c.7237G>A p.D2413N | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAPOR1 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- ERO1B | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, varscan2
- GSE1 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2
- HEATR6 | c.802-1G>C p.X268_splice | Splice Site (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- HSPA4L | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IRX5 | c.480_490del p.S161Rfs*12 | Frame Shift Del (DEL) | VAF 56/400 reads (14%) | called by pindel, varscan2
- KCTD21 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 23/313 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2
- LDHC | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 31/242 reads (13%) | called by muse, mutect2, varscan2
- MAGEB17 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MAS1L | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MDC1 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MINDY2 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- MRPL24 | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- N4BP2L2 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NIP7 | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NPHP4 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR5AS1 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5V1 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PARD3 | c.2655G>C p.K885N | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCARE | c.3709_3710insACA p.G1236_S1237insN | In Frame Ins (INS) | VAF 46/231 reads (20%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PCDHB12 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PLA2G12A | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- PTPN13 | c.1690A>C p.K564Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- QPCT | c.547-1G>C p.X183_splice | Splice Site (SNP) | VAF 16/67 reads (24%) | called by muse, varscan2
- RHOXF2 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.058); called by mutect2, varscan2
- SAMSN1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SCAPER | c.3468del p.R1156Sfs*16 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | called by mutect2, pindel*, varscan2
- SEC61G | c.55A>T p.I19F | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SETBP1 | c.2922del p.Y974* | Frame Shift Del (DEL) | VAF 83/557 reads (15%) | called by mutect2, pindel, varscan2
- SLK | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- SPINK9 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- STK11 | c.536dup p.N181Efs*85 | Frame Shift Ins (INS) | VAF 24/110 reads (22%) | called by mutect2, pindel, varscan2
- TECR | c.607-2A>T p.X203_splice | Splice Site (SNP) | VAF 119/481 reads (25%) | called by muse, mutect2, varscan2
- TNMD | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAC | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TRIM4 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- TRIML2 | c.1225del p.S409Pfs*56 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | called by mutect2, pindel, varscan2
- TRPM6 | c.2589G>C p.E863D | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- UBE2L3 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- VWA8 | c.4193_4197del p.D1398Vfs*4 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | called by mutect2, pindel
- ZCCHC2 | c.327_328del p.Q110Afs*210 | Frame Shift Del (DEL) | VAF 32/194 reads (16%) | called by pindel, varscan2
- ZNF195 | c.508del p.R170Efs*3 (on ENST00000399602 / NM_001130520.3; = p.R98Efs*3 on NM_007152.5) | Frame Shift Del (DEL) | VAF 30/130 reads (23%) | called by mutect2, pindel
- ZNF492 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ZNF655 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF717 | c.1282dup p.C428Lfs*2 | Frame Shift Ins (INS) | VAF 62/274 reads (23%) | called by pindel, varscan2
- ADAMTS4 | c.2214C>T p.L738= | Silent (SNP) | VAF 39/282 reads (14%) | catalogued as COSV63490799; called by muse, mutect2, varscan2
- ADCY8 | c.2457T>A p.T819= | Silent (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- ADD2 | c.696C>T p.A232= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1373876481, COSV52466346; called by muse, varscan2
- ANKRD53 | c.213G>A p.A71= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as rs782182085, COSV55538323; called by muse, mutect2, varscan2
- CACNA1E | c.6621G>A p.L2207= (on ENST00000367573 / NM_001205293.3; = p.L2164= on NM_000721.4) | Silent (SNP) | VAF 45/239 reads (19%) | catalogued as COSV62407824; called by muse, mutect2, varscan2
- CARD9 | c.639C>G p.L213= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as COSV53735383; called by muse, mutect2, varscan2
- CCDC63 | c.1473C>G p.L491= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV57529104, COSV57529724; called by muse, mutect2, varscan2
- CDAN1 | c.162G>A p.L54= | Silent (SNP) | VAF 34/272 reads (13%) | catalogued as COSV51168961; called by muse, mutect2, varscan2
- CDH22 | c.1173C>A p.P391= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- CFAP298 | c.726G>A p.L242= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV51592427, COSV51592894; called by muse, mutect2, varscan2
- CLPP | c.174C>G p.L58= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs753478927, COSV55537004; called by muse, mutect2, varscan2
- COP1 | c.1449G>A p.K483= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV100443634, COSV58172115; called by muse, mutect2, varscan2
- CRELD1 | c.51C>T p.L17= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as rs375937769; called by muse, mutect2, varscan2
- CYP11B2 | c.1365G>T p.L455= | Silent (SNP) | VAF 56/314 reads (18%) | called by muse, varscan2
- DOP1B | c.426C>T p.P142= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV54281048; called by muse, mutect2, varscan2
- DSG3 | c.1548G>A p.L516= | Silent (SNP) | VAF 40/267 reads (15%) | catalogued as rs1025859492, COSV57124741; called by muse, mutect2, varscan2
- DYSF | c.3243C>T p.L1081= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as rs144936357; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EIF4G3 | c.4680G>T p.G1560= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV51688599; called by muse, mutect2, varscan2
- ERMN | c.417C>G p.L139= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV68075519; called by muse, mutect2, varscan2
- FAM83H | c.1128C>G p.L376= | Silent (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- FANCE | c.1455C>T p.T485= | Silent (SNP) | VAF 65/365 reads (18%) | catalogued as COSV100003566, COSV57690582; called by muse, mutect2, varscan2
- FMN2 | c.3267C>A p.P1089= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, varscan2
- GRID2 | c.1302G>A p.L434= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- GUCY2D | c.2820G>T p.R940= | Silent (SNP) | VAF 46/188 reads (24%) | called by muse, mutect2, varscan2
- KDM4A | c.2916C>G p.V972= | Silent (SNP) | VAF 36/215 reads (17%) | catalogued as COSV53517622; called by muse, mutect2, varscan2
- KIAA1614 | c.1722T>C p.G574= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV62551393; called by muse, mutect2, varscan2
- LRP1B | c.6195G>A p.E2065= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- MBOAT7 | c.1026C>T p.V342= | Silent (SNP) | VAF 69/166 reads (42%) | catalogued as rs1360770739, COSV55476860; called by muse, mutect2, varscan2
- MSC | c.528G>A p.V176= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV57697194; called by muse, varscan2
- NCOR2 | c.6924G>A p.T2308= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs372054945; called by muse, mutect2, varscan2
- NIPBL | c.7242C>T p.L2414= | Silent (SNP) | VAF 55/217 reads (25%) | catalogued as COSV56959333; called by muse, mutect2, varscan2
- OBSCN | c.18606C>A p.P6202= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV52802828; called by muse, mutect2, varscan2
- OCA2 | c.2472G>A p.G824= | Silent (SNP) | VAF 53/430 reads (12%) | catalogued as COSV62352464; called by muse, mutect2, varscan2
- OR13C9 | c.843C>A p.S281= | Silent (SNP) | VAF 48/173 reads (28%) | catalogued as rs779410055; called by muse, mutect2, varscan2
- OR4C6 | c.633C>T p.I211= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as COSV100051880, COSV58605245; called by muse, mutect2, varscan2
- PCDHGB2 | c.2220C>A p.L740= | Silent (SNP) | VAF 44/168 reads (26%) | catalogued as COSV53993257; called by muse, mutect2, varscan2
- PCK1 | c.534G>T p.T178= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as rs1394499113, COSV60127873, COSV60129940; called by muse, mutect2, varscan2
- PIK3R2 | c.99G>C p.V33= | Silent (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- POT1 | c.183C>T p.L61= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs1455799309, COSV62932709; ClinVar: likely benign; called by muse, mutect2
- PYGM | c.2010G>A p.A670= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs774235610, COSV51222528; called by muse, mutect2
- RAB39A | c.36C>T p.I12= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV57694829; called by muse, mutect2, varscan2
- RINT1 | c.1794C>G p.L598= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as COSV57559625; called by muse, mutect2, varscan2
- RTTN | c.5713C>T p.L1905= | Silent (SNP) | VAF 37/185 reads (20%) | catalogued as COSV55348796; called by muse, mutect2, varscan2
- SBNO1 | c.3822A>G p.A1274= (on ENST00000420886; = p.A1273= on NM_018183.5) | Silent (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- SLC25A27 | c.672T>C p.L224= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV64928431; called by muse, mutect2, varscan2
- SNX18 | c.1671G>A p.L557= | Silent (SNP) | VAF 34/218 reads (16%) | catalogued as COSV57989534; called by muse, mutect2, varscan2
- SPINDOC | c.279G>A p.V93= | Silent (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2, varscan2
- SSR1 | c.39C>T p.L13= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as rs939529154, COSV55203843; called by muse, mutect2, varscan2
- ST3GAL3 | c.666C>T p.I222= (on ENST00000361392 / NM_174964.4; = p.I207= on NM_006279.5) | Silent (SNP) | VAF 66/337 reads (20%) | catalogued as COSV53517641; called by muse, varscan2
- STX5 | c.1026C>T p.I342= | Silent (SNP) | VAF 46/200 reads (23%) | catalogued as rs774057211, COSV53675573; called by muse, mutect2, varscan2
- SYT13 | c.885C>T p.I295= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- TANC2 | c.5805G>A p.L1935= | Silent (SNP) | VAF 41/197 reads (21%) | catalogued as COSV67338187; called by muse, mutect2, varscan2
- TMPRSS15 | c.2964G>A p.V988= | Silent (SNP) | VAF 57/371 reads (15%) | catalogued as COSV53044682; called by muse, mutect2, varscan2
- TSPAN16 | c.702C>A p.R234= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- TTYH3 | c.675C>T p.L225= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs142865110; called by muse, mutect2, varscan2
- VPS33A | c.966C>T p.F322= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs763113271, COSV57358131; called by muse, varscan2
- WRNIP1 | c.1263C>T p.A421= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV66356233; called by muse, mutect2, varscan2
- ZBTB18 | c.351G>C p.L117= | Silent (SNP) | VAF 46/325 reads (14%) | catalogued as COSV62397982, COSV62398007; called by muse, mutect2, varscan2
- ZNF226 | c.1173C>T p.F391= | Silent (SNP) | VAF 25/222 reads (11%) | catalogued as COSV56196671; called by muse, mutect2, varscan2
- ZNF574 | c.138G>A p.L46= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as COSV55905580; called by muse, mutect2, varscan2
- ZNF628 | c.1407G>A p.L469= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV52701240; called by muse, mutect2, varscan2
- AAK1 | c.*9842C>G | 3'UTR (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- ANP32A | c.54+2468C>G | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- CHMP1A | c.7+38G>C | Intron (SNP) | VAF 45/201 reads (22%) | catalogued as rs764222059; called by muse, mutect2, varscan2
- EFCAB7 | c.947-2150T>A | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- EIF2B4 | c.590+37G>C | Intron (SNP) | VAF 44/265 reads (17%) | called by muse, mutect2, varscan2
- FAM157A | n.37G>T | RNA (SNP) | VAF 42/402 reads (10%) | called by muse, mutect2
- FAM186B | c.96+55G>A | Intron (SNP) | VAF 16/68 reads (24%) | called by muse, varscan2
- FBRS | chr16:30659941 C>T | 5'Flank (SNP) | VAF 41/256 reads (16%) | catalogued as rs1316442136; called by muse, varscan2
- FBXO2 | c.522-11A>G | Intron (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- GNL2 | c.909+806C>T | Intron (SNP) | VAF 41/277 reads (15%) | called by muse, mutect2, varscan2
- GOLGA6L17P | n.1156G>A | RNA (SNP) | VAF 178/680 reads (26%) | called by muse, varscan2
- GPC1 | c.167-919C>A | Intron (SNP) | VAF 16/103 reads (16%) | called by muse, varscan2
- HSPA9 | c.1728+25T>C | Intron (SNP) | VAF 56/201 reads (28%) | called by muse, mutect2, varscan2
- KLF8 | c.-14C>T | 5'UTR (SNP) | VAF 26/78 reads (33%) | catalogued as rs372265867; called by muse, mutect2, varscan2
- LYPD1 | c.-176G>A | 5'UTR (SNP) | VAF 15/54 reads (28%) | catalogued as rs765283733; called by muse, mutect2, varscan2
- MAMLD1 | c.*347G>A | 3'UTR (SNP) | VAF 7/16 reads (44%) | catalogued as rs1557409176, COSV53378171; called by muse, mutect2, varscan2
- MTERF4 | c.706-238T>C | Intron (SNP) | VAF 30/156 reads (19%) | called by mutect2, varscan2
- NDUFA7 | chr19:8321383 G>A | 5'Flank (SNP) | VAF 15/57 reads (26%) | catalogued as rs763710582; called by muse, mutect2, varscan2
- NDUFS3 | c.382-45C>T | Intron (SNP) | VAF 54/250 reads (22%) | catalogued as rs1472695264; called by muse, mutect2, varscan2
- NT5DC2 | c.121+1021G>C | Intron (SNP) | VAF 30/87 reads (34%) | catalogued as COSV61053124; called by muse, mutect2, varscan2
- NTF3 | c.-1G>A | 5'UTR (SNP) | VAF 30/124 reads (24%) | catalogued as COSV58418020, COSV58418177; called by muse, varscan2
- OFCC1 | n.67dup | RNA (INS) | VAF 27/163 reads (17%) | called by mutect2, pindel, varscan2
- PKD1L2 | n.483C>G | RNA (SNP) | VAF 28/168 reads (17%) | catalogued as rs780116125; called by muse, mutect2, varscan2
- POLA1 | c.2947-21020C>G | Intron (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- PSME3 | c.-5C>T | 5'UTR (SNP) | VAF 35/163 reads (21%) | catalogued as rs746119256, COSV99513732; called by muse, mutect2, varscan2
- RO60 | chr1:193091626 G>T | 3'Flank (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- RPL3 | c.-1G>C | 5'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- SAA2 | chr11:18242798 G>A | 3'Flank (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- SERPINB10 | c.-29C>A | 5'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- SRI | c.52-40G>T | Intron (SNP) | VAF 55/284 reads (19%) | catalogued as rs562947449; called by muse, mutect2, varscan2
- SYNE1 | c.26154-2601C>T | Intron (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2161C>G | Intron (SNP) | VAF 11/140 reads (8%) | catalogued as rs1208920928, COSV60358695; called by muse, mutect2
- TRAV36DV7 | chr14:22222421 G>C | 5'Flank (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- TTC29 | c.977+2080C>T | Intron (SNP) | VAF 31/125 reads (25%) | catalogued as rs1325883354; called by muse, mutect2, varscan2
- TTN | c.10360+1775G>C | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as rs1458319550, COSV59950440, COSV60212092; called by muse, mutect2, varscan2
- UBL4A | c.155-62C>T | Intron (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- UBR3 | c.4368-1446_4368-1440delinsTTTTATT | Intron (ONP) | VAF 6/59 reads (10%) | called by mutect2*, pindel
- USP34 | chr2:61186720 C>T | 3'Flank (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- VPS33B | c.701-9C>G | Intron (SNP) | VAF 74/329 reads (22%) | called by muse, mutect2, varscan2
- ZAN | c.7787+29G>A | Intron (SNP) | VAF 25/59 reads (42%) | catalogued as rs776195518; called by muse, mutect2, varscan2
